TCGA case TCGA-2Z-A9JK — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8b88441-16c7-4201-9c01-3e7237d18eee

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 50 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 50.8 years (18,540 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,186 days (3.2 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 51.6 years (18,864 days); Days to diagnosis: 324 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 343 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (5 entries)
- Day 324 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 324 days.
- Days to follow up: 1,010 days (2.8 years); Disease response: With Tumor.
- Days to follow up: 1,186 days (3.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Other.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Normal.
- Leukocytes: Normal.
- Calcium: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 102.1 kg; Height: 185.5 cm; BMI: 29.7.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Pack years smoked: 60.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2Z-A9JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-2Z-A9JK-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-2Z-A9JK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2Z-A9JK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 5; Treatment outcome first course: Stable Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Stable Disease; Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; Performance status timing: Post Secondary Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,186 days; disease-specific survival: no event (censored), 1,186 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 324 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2Z-A9JK-01A-11D-A42I-01): tumor purity 0.48, ploidy 1.97, whole-genome doublings 0.
